Surgical pathology report (de-identified scan), TCGA case TCGA-CV-6962, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma), tissue source site MD Anderson Cancer Center, specimen TCGA-CV-6962-01A (Primary Tumor).

[page 1 of 2]
SUPPLEMENTAL REPORT

DIAGNOSIS:

- (C) TOTAL LARYNGECTOMY:
SQUAMOUS CARCINOMA IN PERICHONDRIUM.
Cartilage, no tumor present.

Entire report and diagnosis completed by: [REDACTED]
Report released by: [REDACTED]

DIAGNOSIS

- (A) RIGHT THYROID:
Nodular goiter.
- (B) SKIN THYROID:
Nodular goiter.
- (C) TOTAL LARYNGECTOMY, PARTIAL PHARYNGECTOMY:
Bilateral transglottic poorly differentiated squamous carcinoma
with extensive vascular invasion; tumor involving three
epiglottic and paraglottic spaces and skeletal muscle of the
neck. Tumor in vascular spaces at submucosa close to the
margins of excision, less than 1 mm (see comment).
- (D) SKIN OF NECK:
Subcutaneous tissue, no tumor.

Entire report and diagnosis completed by: [REDACTED]
Report released by: [REDACTED]

COMMENT

The blood vessels of the right and left mucosal margins are invaded by tumor.
Technically these margins should be considered positive, although the tumor
is only 1 mm from the margin of excision.

[page 2 of 2]
Case type: Surgical History

GROSS DESCRIPTION

(A) RIGHT THYROID - An unoriented, round fragment of tan-brown soft tissue (3.4 x 2.8 x 1.8 cm). Identified in the central portion of the specimen is a calcified cystic mass (0.7 x 0.6 x 0.3 cm) composed of hard gray-white material.

INK CODE: Black- external surface.

SECTION CODE: A1-A5, multiple representative sections; A6, representative section of calcified cystic mass for decalcification.

(B) LEFT THYROID - A lobe of thyroid (2.5 x 1.0 x 1.2 cm). The parenchyma is firm, tan-red in color with increased fibrous tissue. No discrete lesions are identified. Specimen is marked with black and ink and representative sections submitted in cassettes B1-B3.

(C) TOTAL LARYNGECTOMY, PARTIAL PHARYNGECTOMY - The specimen (8.5 x 8.0 x 4.5 cm overall) consist of larynx (7.5 x 8.5 x 2.5 cm), skin of tracheostomy site (4.5 x 2.5 cm, hyoid bone and anterior soft tissue).

There is a firm, infiltrating tan-white tumor (4.2 x 3.2 x 1.1 cm) ascending from the base of the epiglottis to the subglottic region and involving the right true and false cords, midline and left true and false. The tumor extends close to the right mucosal margin. The tumor also extends anteriorly into the preepiglottic space, up to adjacent hyoid bone and inferiorly to into skeletal muscle.

The adjacent mucosa around the tracheostomy site is erythematous. No other lesions are identified.

SECTION CODE: C1-C5, mucosal margins from right to left; C6, tracheal margin; C7-C10, prepiglottic space; C11, epiglottis; C12, midline; C13, area of right vocal cord; C14, area of left vocal cord; C15, tracheostomy site; C16-C18, additional sections of tumor.

(D) NECK SKIN - Two irregularly shaped, unoriented fragments of tan skin (6.1 x 2.0 x 0.5 cm and 7.2 x 1.5 x 0.5 cm). Representative sections are submitted as B1 and B2.

Source: NCI Genomic Data Commons file 85159531-1c35-4352-a85b-7dc83f515e0a (TCGA-CV-6962.87FC399E-1E82-4883-8D0B-DD1F8BBFD953.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).